Somatic mutation profile of tumor specimen MP2PRT-PARFIZ-TMP1-A (aliquot MP2PRT-PARFIZ-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARFIZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.2 years (2,621 days).
Specimen MP2PRT-PARFIZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cc6aa36-0b46-46af-821d-9003b337a967.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARFIZ-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARFIZ-NM1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56c74db3-61a8-42c5-aaf0-81a9685712e8

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Splice Region 2, Silent 2, Nonsense Mutation 2, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 94/312 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP8B2 | c.2796C>T p.T932= (on ENST00000672630; = p.T899= on NM_001367934.1 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 97/209 reads (46%) | catalogued as rs781532937; called by muse, mutect2, varscan2
- CD80 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 91/241 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs780121133, COSV99958236; called by muse, mutect2, varscan2
- FGFR2 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 106/486 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV60643607; called by muse, mutect2, varscan2
- OR10S1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 163/402 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV101602445; called by muse, mutect2, varscan2
- SLC35F1 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 194/659 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs775023281; called by muse, mutect2, varscan2
- SYT13 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 167/420 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as rs1235313234; called by muse, mutect2, varscan2
- TBCE | c.1209G>A p.P403= (on ENST00000366601; = p.P466= on NM_003193.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 108/257 reads (42%) | catalogued as rs762799965, COSV64005273; called by muse, mutect2, varscan2
- TLN1 | c.5672G>A p.S1891N | Missense Mutation (SNP) | VAF 168/396 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1389990010; called by muse, mutect2, varscan2
- TRIM2 | c.1843C>T p.R615* (on ENST00000437508; = p.R642* on NM_015271.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/386 reads (5%) | catalogued as COSV58630857; called by muse, mutect2
- TUBAL3 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 191/734 reads (26%) | catalogued as rs143994010; called by muse, mutect2, varscan2
- IGKV4-1 | chr2:88886149 del CTC | In Frame Del (DEL) | VAF 71/190 reads (37%) | called by pindel, varscan2
- SGMS1 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 127/577 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D12 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 251/1033 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2orf42 | c.1191T>C p.D397= | Silent (SNP) | VAF 36/268 reads (13%) | called by muse, mutect2, varscan2
- MATK | c.918C>T p.H306= (on ENST00000310132 / NM_139355.3; = p.H307= on NM_002378.4) | Silent (SNP) | VAF 142/422 reads (34%) | catalogued as COSV59556039; called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106506995 ins GGTGCGGAA | 3'Flank (INS) | VAF 58/142 reads (41%) | called by pindel, varscan2
